Somatic mutation profile of tumor specimen C3N-01021-01 (aliquot CPT0104970009) from CPTAC case C3N-01021, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 44.2 years (16,139 days).
Specimen C3N-01021-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 658a6b25-072d-484a-87a2-c0c29a0ca69a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01021-31 (Blood Derived Normal), aliquot CPT0107560002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c1813f9-8bbb-4724-be45-aff570f4da5e

The open-access MAF lists 55 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 13, 3'UTR 4, Intron 2, Frame Shift Del 2, Nonsense Mutation 2, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD7 | c.7879C>T p.R2627* | Nonsense Mutation (SNP) | VAF 10/278 reads (4%) | catalogued as rs1064793346, CM060902, COSV71113635; ClinVar: pathogenic; called by muse, mutect2
- EGFR | c.2156G>C p.G719A | Missense Mutation (SNP) | VAF 79/356 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913428, COSV51769339, COSV51771914, COSV51779524; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- EGFR | c.2582T>A p.L861Q | Missense Mutation (SNP) | VAF 100/540 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs121913444, COSV51766344, COSV51766618; ClinVar: pathogenic / likely pathogenic / drug response; called by muse, mutect2, varscan2
- ATP4A | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.903); catalogued as rs781628677, COSV52865764; called by muse, mutect2, varscan2
- CLCNKA | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 67/541 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139424076; called by muse, mutect2, varscan2
- CRNN | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 48/396 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55122128; called by mutect2, varscan2
- DMXL2 | c.8873C>T p.T2958I | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as rs1248123890; called by muse, mutect2
- FLG | c.1096C>A p.R366S | Missense Mutation (SNP) | VAF 54/650 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as rs371936330, COSV100912045, COSV64250428; called by muse, mutect2
- MYCN | c.905G>A p.R302H | Missense Mutation (SNP) | VAF 62/353 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.36); catalogued as rs140581169; called by muse, mutect2, varscan2
- NKX6-3 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1361342906; called by muse, mutect2, varscan2
- OR2A12 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 73/408 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as rs770997909, COSV68821180; called by muse, mutect2, varscan2
- OR5M8 | c.139C>T p.L47F | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377613054; called by muse, mutect2, varscan2
- PLS3 | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs782053765; called by mutect2, varscan2
- SNX27 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV100919100, COSV64326999; called by muse, mutect2, varscan2
- ANKUB1 | c.47T>C p.V16A | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2
- ARHGEF2 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- BRWD3 | c.592G>C p.G198R | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC8 | c.1440_1441del p.F480Lfs*50 | Frame Shift Del (DEL) | VAF 34/368 reads (9%) | called by mutect2, pindel
- DHX57 | c.2778del p.Y927Mfs*8 | Frame Shift Del (DEL) | VAF 22/163 reads (13%) | called by mutect2, pindel, varscan2
- DNAH6 | c.1235A>T p.E412V | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2
- ENPEP | c.2779C>A p.Q927K | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.067); called by muse, mutect2
- EPHA1 | c.1745G>T p.R582L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, varscan2
- FASTKD1 | c.1918T>G p.L640V | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HADHB | c.20C>G p.P7R | Missense Mutation (SNP) | VAF 67/409 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IMPACT | c.253T>A p.L85I | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- ITGA8 | c.1565G>C p.R522T | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2
- MAP6 | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.067); called by muse, mutect2
- MOV10 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MUC16 | c.10394C>T p.P3465L | Missense Mutation (SNP) | VAF 65/420 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PID1 | c.459G>T p.E153D (on ENST00000354069 / NM_001330156.1; = p.E151D on NM_017933.5) | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RAD51C | c.611T>G p.I204S | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- SPC25 | c.622T>C p.S208P | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTBN5 | c.834C>A p.Y278* | Nonsense Mutation (SNP) | VAF 40/366 reads (11%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.369C>T p.S123= | Silent (SNP) | VAF 91/272 reads (33%) | catalogued as COSV64159775; called by muse, mutect2, varscan2
- CBLN1 | c.120C>T p.S40= | Silent (SNP) | VAF 65/207 reads (31%) | catalogued as COSV54655090; called by muse, mutect2, varscan2
- CDH4 | c.585C>T p.S195= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs374076466, COSV100848438; called by muse, mutect2, varscan2
- CLCN6 | c.327G>A p.K109= | Silent (SNP) | VAF 37/342 reads (11%) | catalogued as rs759929293, COSV100411778, COSV56742917; called by muse, mutect2, varscan2
- HEATR5B | c.492A>G p.L164= | Silent (SNP) | VAF 27/214 reads (13%) | catalogued as rs1053152309; called by muse, mutect2, varscan2
- IGHV4-39 | c.111G>A p.L37= | Silent (SNP) | VAF 76/574 reads (13%) | catalogued as rs772122286; called by muse, varscan2
- IGHV4-39 | c.75G>A p.L25= | Silent (SNP) | VAF 67/454 reads (15%) | catalogued as rs1301096024; called by muse, varscan2
- KIF2C | c.1629G>A p.K543= | Silent (SNP) | VAF 30/382 reads (8%) | called by muse, mutect2
- POTEF | c.2448C>T p.R816= | Silent (SNP) | VAF 109/611 reads (18%) | catalogued as rs562326654, COSV100665255, COSV62545450; called by muse, mutect2, varscan2
- PPP1R3F | c.372G>A p.A124= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- RBFOX1 | c.1017C>T p.A339= | Silent (SNP) | VAF 29/254 reads (11%) | catalogued as rs148909710; called by muse, mutect2, varscan2
- SALL2 | c.2130C>T p.V710= | Silent (SNP) | VAF 51/215 reads (24%) | catalogued as COSV58102853; called by muse, mutect2, varscan2
- USP36 | c.783C>T p.V261= | Silent (SNP) | VAF 33/185 reads (18%) | catalogued as rs574564216; called by muse, mutect2, varscan2
- AMFR | c.*613T>G | 3'UTR (SNP) | VAF 73/287 reads (25%) | called by muse, mutect2, varscan2
- AMFR | c.*532G>C | 3'UTR (SNP) | VAF 28/115 reads (24%) | called by muse, varscan2
- AMFR | c.*379G>A | 3'UTR (SNP) | VAF 50/191 reads (26%) | called by muse, varscan2
- AP001496.3 | chr18:5238289 C>T | 3'Flank (SNP) | VAF 24/173 reads (14%) | called by muse, mutect2, varscan2
- CCDC180 | chr9:97307359 G>C | 5'Flank (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- MARF1 | chr16:15643319 C>G | 5'Flank (SNP) | VAF 60/197 reads (30%) | catalogued as rs765211962; called by muse, mutect2, varscan2
- NEUROD1 | c.*29A>G | 3'UTR (SNP) | VAF 43/254 reads (17%) | called by muse, mutect2, varscan2
- SPTA1 | c.6531-18C>T | Intron (SNP) | VAF 38/336 reads (11%) | catalogued as COSV63755480; called by muse, mutect2, varscan2
- SRRM2 | c.8021+526G>A | Intron (SNP) | VAF 25/278 reads (9%) | called by muse, mutect2
